FM case AD4282 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Other and unspecified major salivary glands.
https://portal.gdc.cancer.gov/cases/04724711-36dc-43d4-bdf5-1f8763d08bd0

Female, 21.8 years: Adenoid cystic carcinoma (ICD-O-3 8200/3) of the major salivary gland; specimen biopsied or resected from the head, face or neck. Tumor nuclei on the sequenced sample's slide: 70% (pathologist estimate recorded by GDC). Sample type: Tumor.
